Somatic mutation profile of tumor specimen TCGA-06-0745-01A (aliquot TCGA-06-0745-01A-01W-0348-08) from TCGA case TCGA-06-0745, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.9 years (21,884 days).
Specimen TCGA-06-0745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13ed09ea-81c3-4cdb-a1fd-965cdca8c6a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0745-10A (Blood Derived Normal), aliquot TCGA-06-0745-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5658815c-0a91-42cd-9b3e-b88765db50ed

The open-access MAF lists 71 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Frame Shift Ins 16, Silent 12, Nonsense Mutation 5, Intron 2, Splice Site 2, RNA 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 146/1049 reads (14%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- MVK | c.417dup p.G140Rfs*47 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs104895373; ClinVar: not provided / pathogenic; called by pindel, varscan2
- ABCB1 | c.787A>T p.T263S | Missense Mutation (SNP) | VAF 32/586 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV55946003; called by muse, mutect2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 27/244 reads (11%) | catalogued as rs767549806; called by mutect2, varscan2
- AKAP6 | c.3652G>C p.E1218Q | Missense Mutation (SNP) | VAF 275/441 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55206236, COSV55210771; called by muse, mutect2, varscan2
- AREG | c.334dup p.Q112Pfs*7 | Frame Shift Ins (INS) | VAF 16/90 reads (18%) | catalogued as rs757742243; called by mutect2, varscan2
- ART1 | c.727A>T p.I243F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51703064; called by muse, mutect2, varscan2
- ATE1 | c.170+2del p.X57_splice | Splice Site (DEL) | VAF 69/112 reads (62%) | catalogued as COSV56443113; called by mutect2, pindel, varscan2
- C8orf34 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 65/180 reads (36%) | catalogued as rs748338743, COSV100447456, COSV61372204; called by muse, mutect2, varscan2
- CHD9 | c.480T>A p.H160Q | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV68297211; called by muse, mutect2, varscan2
- CHM | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 80/88 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV63300047; called by muse, mutect2, varscan2
- CIITA | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 85/189 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs376464815; called by muse, mutect2, varscan2
- CNTNAP1 | c.1672T>G p.S558A | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV52850097; called by muse, mutect2
- DLD | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 441/1651 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52737006; called by muse, mutect2, varscan2
- EGR2 | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 79/124 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV54346288; called by muse, mutect2, varscan2
- EPHX1 | c.400dup p.Q134Pfs*26 | Frame Shift Ins (INS) | VAF 20/165 reads (12%) | catalogued as rs756407271; called by mutect2, varscan2
- FNTB | c.1047dup p.L350Afs*4 | Frame Shift Ins (INS) | VAF 21/146 reads (14%) | catalogued as rs768774237; called by mutect2, varscan2
- FSTL1 | c.694+1G>A p.X232_splice | Splice Site (SNP) | VAF 39/89 reads (44%) | catalogued as COSV55232215; called by muse, mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 24/217 reads (11%) | catalogued as rs768450027; called by mutect2, varscan2
- GTF3C1 | c.4408G>C p.E1470Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as COSV62239239, COSV62244043; called by muse, mutect2, varscan2
- IL25 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV59307306; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 34/302 reads (11%) | catalogued as rs774820321; called by mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 30/193 reads (16%) | catalogued as rs746133895; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 32/129 reads (25%) | catalogued as rs777328830; called by mutect2, varscan2
- MAST4 | c.1715C>T p.T572M (on ENST00000403625 / NM_001164664.2; = p.T383M on NM_015183.3) | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs367779827; called by muse, mutect2, varscan2
- MGARP | c.57dup p.N20Qfs*17 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | catalogued as rs745749792; called by pindel, varscan2
- MUC16 | c.15257G>A p.R5086H | Missense Mutation (SNP) | VAF 269/673 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.193); catalogued as rs533387298, COSV67442388, COSV67493775; called by muse, mutect2, varscan2
- MXRA5 | c.3839G>A p.R1280K | Missense Mutation (SNP) | VAF 220/280 reads (79%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV54225421, COSV99478129; called by muse, mutect2, varscan2
- MYCBP2 | c.1597T>C p.W533R (on ENST00000357337; = p.W571R on NM_015057.5) | Missense Mutation (SNP) | VAF 176/463 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV62011412; called by muse, mutect2, varscan2
- MYOM2 | c.4373C>T p.A1458V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.871); catalogued as rs562106463, COSV50702591; called by muse, mutect2, varscan2
- MYT1L | c.3127G>A p.G1043R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs774591482, COSV67701199; called by muse, mutect2, varscan2
- NCAPD3 | c.2725dup p.Q909Pfs*12 | Frame Shift Ins (INS) | VAF 9/80 reads (11%) | catalogued as rs770284236; called by mutect2, varscan2
- OR4D5 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 160/396 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs564572858, COSV58305578; called by muse, mutect2, varscan2
- OR5K4 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 607/824 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201188789; called by muse, mutect2, varscan2
- PCDHB13 | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); catalogued as rs782557994, COSV53393643; called by muse, mutect2, varscan2
- PCDHB3 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV50564677, COSV50581609; called by muse, mutect2, varscan2
- PCNA | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64770277, COSV64770349; called by muse, mutect2
- PHF7 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1190400968; called by muse, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 51/430 reads (12%) | catalogued as rs749506841; called by mutect2, varscan2
- PPP4R3A | c.1627C>G p.L543V (on ENST00000554943 / NM_001366432.1; = p.L530V on NM_001284280.1) | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.685); catalogued as COSV61503633; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 82/570 reads (14%) | catalogued as rs778683789; called by mutect2, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 28/171 reads (16%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- RB1CC1 | c.1565A>G p.K522R | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs766968433, COSV50243445; called by muse, mutect2, varscan2
- RGL4 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 34/46 reads (74%) | catalogued as COSV51943249; called by muse, mutect2, varscan2
- SBF1 | c.1864G>C p.D622H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62366031; called by muse, mutect2, varscan2
- SEC31A | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 37/121 reads (31%) | catalogued as COSV52341986; called by muse, mutect2, varscan2
- SMOX | c.908dup p.R304Qfs*4 | Frame Shift Ins (INS) | VAF 20/156 reads (13%) | catalogued as rs746816975; called by mutect2, varscan2
- SMYD3 | c.876A>C p.K292N (on ENST00000490107 / NM_001375962.1; = p.K233N on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV63625800; called by muse, mutect2, varscan2
- SNX9 | c.960A>T p.E320D | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV67583345; called by muse, mutect2, varscan2
- TRPM1 | c.4649C>A p.S1550* | Nonsense Mutation (SNP) | VAF 218/310 reads (70%) | catalogued as COSV56631160; called by muse, mutect2, varscan2
- ZNF813 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 148/212 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV67175888; called by muse, mutect2, varscan2
- BCL2 | c.104_106del p.V35del | In Frame Del (DEL) | VAF 13/26 reads (50%) | called by mutect2, pindel, varscan2
- DOCK5 | c.2444C>A p.A815E | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TCF19 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- ZNF230 | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2
- AHNAK | c.3156C>T p.G1052= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV57205158; called by muse, mutect2, varscan2
- CHEK2 | c.192G>A p.E64= | Silent (SNP) | VAF 63/181 reads (35%) | catalogued as COSV60416501; called by muse, varscan2
- CLSTN1 | c.1656G>A p.K552= (on ENST00000377298 / NM_001009566.3; = p.K542= on NM_014944.4) | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs986579316; called by muse, mutect2
- COL28A1 | c.2655C>T p.N885= | Silent (SNP) | VAF 82/235 reads (35%) | catalogued as rs368864863; called by muse, mutect2, varscan2
- DNASE1 | c.144G>C p.V48= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- FAM120A | c.1743C>A p.I581= | Silent (SNP) | VAF 79/295 reads (27%) | catalogued as COSV52901716; called by muse, mutect2, varscan2
- KIF18A | c.2151G>A p.P717= | Silent (SNP) | VAF 75/252 reads (30%) | catalogued as rs575102434, COSV54181447, COSV54184532; called by muse, mutect2, varscan2
- LCT | c.2079C>T p.N693= | Silent (SNP) | VAF 176/656 reads (27%) | catalogued as rs767194078, COSV51544826; called by muse, mutect2, varscan2
- OR5T2 | c.732T>C p.S244= | Silent (SNP) | VAF 24/909 reads (3%) | called by muse, mutect2
- PCDH11X | c.228A>T p.R76= | Silent (SNP) | VAF 322/374 reads (86%) | catalogued as COSV53446317; called by muse, mutect2, varscan2
- RYR2 | c.12996C>G p.A4332= | Silent (SNP) | VAF 176/448 reads (39%) | catalogued as COSV63665871; called by muse, mutect2, varscan2
- TFEC | c.585A>G p.E195= | Silent (SNP) | VAF 51/451 reads (11%) | catalogued as COSV55397980; called by muse, mutect2, varscan2
- CHEK2 | c.-1G>C | 5'UTR (SNP) | VAF 40/134 reads (30%) | catalogued as COSV60426160; called by muse, varscan2
- DNM1P46 | n.512G>A | RNA (SNP) | VAF 33/78 reads (42%) | catalogued as rs376517074; called by muse, mutect2, varscan2
- RMDN2 | c.453-21997A>T | Intron (SNP) | VAF 150/347 reads (43%) | catalogued as COSV52229611; called by muse, mutect2, varscan2
- THRA | c.1110+102C>A | Intron (SNP) | VAF 16/31 reads (52%) | catalogued as COSV52846199; called by muse, mutect2, varscan2
